Gene-level copy-number profile of tumor specimen ALCH-B3ZX-TTP1-A from ALCHEMIST case ALCH-B3ZX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.7 years (23,997 days).
Specimen ALCH-B3ZX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7edbdeb8-54de-438a-9265-185eab3d6812.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3ZX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/3b95aa42-1ca8-4b86-9f2c-97ff74e8dabc

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 680; copy number 1: 34,560; copy number 2: 22,968; copy number 3: 668; copy number 4: 4; copy number 5: 6; copy number 6: 6; copy number 7: 2; copy number 20: 1; copy number 52: 1.

Homozygous deletions (total copy number 0; autosomes only): 168 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–12,947,580, 1 gene (within-gene range 0–1): PRAMEF6.
- chr1:13,222,705–13,275,627, 4 genes: PRAMEF18, PRAMEF31P, PRAMEF5, PRAMEF32P.
- chr2:24,825,610–24,826,717, 1 gene (within-gene range 0–1): AC012073.1.
- chr2:89,009,982–89,254,015, 25 genes (within-gene range 0–1): IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr2:89,936,859–90,005,629, 7 genes: IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24.
- chr2:90,100,236–90,100,738, 1 gene: IGKV1D-16.
- chr2:90,121,786–90,221,384, 8 genes (within-gene range 0–1): IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8.
- chr2:90,359,809–91,621,421, 5 genes (within-gene range 0–1): AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1.
- chr2:91,736,726–91,767,701, 3 genes: AC027612.1, KMT5AP2, AC027612.3.
- chr4:49,502,145–49,524,185, 4 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8.
- chr6:107,065,182–107,115,515, 1 gene: BEND3.
- chr9:61,615,835–61,666,386, 4 genes: FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr9:63,719,864–63,762,824, 4 genes: CDRT15P7, AL772155.1, AL772155.2, MYO5BP3.
- chr9:67,832,765–67,920,552, 2 genes (within-gene range 0–1): ANKRD20A1, RNU6-368P.
- chr9:68,302,867–68,531,061, 7 genes: FOXD4L3, AL353608.3, AL353608.1, PGM5, PGM5-AS1, AL161457.2, AL161457.1.
- chr9:96,246,462–96,250,393, 1 gene (within-gene range 0–1): HSD17B3-AS1.
- chr11:1,919,703–1,938,706, 1 gene: TNNT3.
- chr11:31,784,779–31,817,961, 1 gene (within-gene range 0–1): PAX6.
- chr14:18,333,726–18,419,273, 3 genes: CR383658.1, CR383658.2, BNIP3P6.
- chr15:85,958,717–85,958,971, 1 gene: AC104229.1.
- chr17:45,844,881–45,847,067, 1 gene (within-gene range 0–1): SPPL2C.
- chr19:24,098,425–24,163,425, 3 genes (within-gene range 0–1): BNIP3P40, AC073534.2, AC073534.1.
- chr19:30,553,956–30,558,058, 1 gene (within-gene range 0–1): AC011504.1.
- chr20:31,465,506–31,484,895, 2 genes: DEFB124, REM1.
- chr20:31,844,303–31,845,604, 1 gene: FOXS1.
- chr20:33,666,498–33,668,525, 2 genes (within-gene range 0–1): ACTL10, ACTL10.
- chr21:7,744,962–13,120,807, 74 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 688 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,172,455–13,179,464, 1 gene, copy number 5: PRAMEF9.
- chr2:90,114,838–90,115,402, 1 gene, copy number 7 (within-gene range 0–7): IGKV3D-15.
- chr3:149,369,022–149,386,583, 3 genes, copy number 3: TM4SF1, TM4SF1-AS1, AC108751.4.
- chr6:163,413,065–163,413,960, 1 gene, copy number 3: CAHM.
- chr7:76,818,377–92,590,393, 177 genes, copy number 3 (broad region; genes not listed).
- chr7:106,372,251–132,648,688, 396 genes, copy number 3 (broad region; genes not listed).
- chr10:33,341,655–33,341,905, 1 gene, copy number 4: AL353600.1.
- chr11:1,947,278–2,001,470, 7 genes, copy number 6–52: MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr11:39,024,631–39,261,213, 3 genes, copy number 3–4: AC021723.2, AC021723.1, RNU6-99P.
- chr12:115,957,905–116,277,693, 1 gene, copy number 3 (within-gene range 2–4): MED13L.
- chr12:116,148,560–116,181,295, 3 genes, copy number 3 (within-gene range 3–4): MIR620, SNRPGP18, AC130895.1.
- chr14:37,556,158–37,596,059, 3 genes, copy number 3–4 (within-gene range 1–4): AL121790.2, AL121790.1, FOXA1.
- chr14:105,620,506–105,626,066, 2 genes, copy number 6–7: IGHG4, MIR8071-1.
- chr15:58,587,507–58,591,676, 1 gene, copy number 3 (within-gene range 1–3): AC018904.1.
- chr15:85,380,571–85,749,358, 1 gene, copy number 3 (within-gene range 1–4): AKAP13.
- chr15:85,579,046–85,670,948, 3 genes, copy number 3 (within-gene range 2–4): AC087286.3, AC087286.2, AC087286.1.
- chr16:32,475,051–32,478,250, 1 gene, copy number 5: ABCD1P3.
- chr16:88,382,959–88,440,757, 1 gene, copy number 5: ZNF469.
- chr17:59,565,558–59,707,626, 4 genes, copy number 3 (within-gene range 2–3): DHX40, AC091271.1, CLTC, PTRH2.
- chr19:186,373–1,279,244, 71 genes, copy number 3 (broad region; genes not listed).
- chr20:31,664,452–31,801,805, 4 genes, copy number 3–4: BCL2L1, BCL2L1-AS1, ABALON, TPX2.
- chr20:35,278,907–35,292,425, 3 genes, copy number 5 (within-gene range 1–5): EIF6, FAM83C-AS1, FAM83C.

Autosomal genes at a single copy (total copy number 1): 32,217. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
